MMRF case MMRF_1286 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5a29aaa2-1320-4e8b-b51d-a57431ca2c32

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.3 years (27,125 days); ISS stage: I; Days to last known disease status: 1,510 days (4.1 years); Days to last follow up: 1,510 days (4.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 40 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 47 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 74 days; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 100 days; Days to treatment end: 100 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 100 days; Days to treatment end: 100 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 268 days; Days to treatment end: 1,018 days (2.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 268 days; Days to treatment end: 920 days (2.5 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 941 days (2.6 years); Days to treatment end: 1,107 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,032 days (2.8 years); Days to treatment end: 1,101 days (3.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,129 days (3.1 years); Days to treatment end: 1,206 days (3.3 years).
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,129 days (3.1 years); Days to treatment end: 1,199 days (3.3 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,129 days (3.1 years); Days to treatment end: 1,205 days (3.3 years).
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone + Pomalidomide; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 1,227 days (3.4 years).
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 1,229 days (3.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -18 (ECOG 0): M Protein 2.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 108 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.578 mg/dL; Immunoglobulin G 38.8 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 3.14 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 9.1 g/dL; Glucose 5.34 mmol/L.
- Day 74 (ECOG 0): M Protein 1.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 93.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.366 mg/dL; Immunoglobulin G 24.8 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 5.93 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 7.9 g/dL; Glucose 5.06 mmol/L.
- Day 165 (ECOG 1): M Protein 1.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 42.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.137 mg/dL; Immunoglobulin G 22.4 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 3.34 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.6 g/dL; Glucose 7.04 mmol/L.
- Day 268 (ECOG 1): M Protein 1.91 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 48.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 24.7 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 3.25 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 8.2 g/dL; Glucose 6.71 mmol/L.
- Day 330 (ECOG 1): M Protein 0.96 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 55.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.693 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 3.21 µg/mL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 78 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 6.77 mmol/L.
- Day 428 (ECOG 1): M Protein 0.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.781 mg/dL; Immunoglobulin G 8.65 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.13 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 5.12 mmol/L.
- Day 509 (ECOG 1): M Protein 0.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.698 mg/dL; Immunoglobulin G 8.17 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 75 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 6.6 mmol/L.
- Day 611 (ECOG 1): M Protein 0.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.473 mg/dL; Immunoglobulin G 8.39 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 64 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.3 g/dL; Glucose 6.66 mmol/L.
- Day 674 (ECOG 2): M Protein 0.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 8.33 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 7.67 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 61 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2 mmol/L; Albumin 26 g/L; Total Protein 6.1 g/dL; Glucose 6.99 mmol/L.
- Day 782 (ECOG 2): M Protein 0.93 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.727 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 3.76 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 4.95 mmol/L.
- Day 872 (ECOG 1): M Protein 0.68 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.692 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 1.85 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 6.6 mmol/L.
- Day 977 (ECOG 1): M Protein 0.88 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 37.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.622 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.03 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 7.76 mmol/L.
- Day 1,073 (ECOG 1): M Protein 1.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 37.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.602 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 4.79 mmol/L.
- Day 1,167 (ECOG 2): M Protein 1.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 42.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 10.3 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 5.18 ×10⁹/L; Platelets 57 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 1.93 mmol/L; Albumin 25 g/L; Total Protein 5.4 g/dL; Glucose 4.73 mmol/L.
- Day 1,256 (ECOG 1): M Protein 1.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 62.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.209 mg/dL; Immunoglobulin G 16.1 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 7.27 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 20.4 ×10⁹/L; Absolute Neutrophil 17.6 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 127 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.13 mmol/L; Albumin 33 g/L; Total Protein 7.2 g/dL; Glucose 6.77 mmol/L.
- Day 1,340 (ECOG 1): M Protein 0.89 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.08 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 5.61 mmol/L.
- Day 1,424 (ECOG 1): M Protein 0.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.142 mg/dL; Immunoglobulin G 9.65 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 3.06 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 6.82 mmol/L.
- Day 1,510 (ECOG 1): M Protein 0.73 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 28.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.193 mg/dL; Immunoglobulin G 9.27 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 6.38 mmol/L.

Other clinical attributes
- Day -18: Weight: 83 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1286_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -18 days.
- Sample MMRF_1286_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -18 days.
